Surgical pathology report (de-identified scan), TCGA case TCGA-44-5644, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-5644-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

- A. R4 lymph node
- B. Right lymph node
- C. Level 10 lymph node
- D. Right lower lobe
- E. Level 7 lymph node

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung mass.

FROZEN SECTION DIAGNOSIS

R-4 lymph nodes, biopsy: Negative for malignancy.

GROSS DESCRIPTION

A. The specimen is received unfixed, labeled "R4 lymph nodes" and consists of multiple pieces of red and black soft tissue measuring 1.3 cm. in greatest aggregate dimension. The entire specimen is submitted for frozen section diagnosis as requested.

B. ived in formalin labeled "R4 lymph node" and consists of 4 pieces of white and black soft tissue

varying

from 1.2 to 1.5 cm. in greatest dimension. RS-1

C. Received in formalin labeled "level 10 lymph node" and consists of 5 pieces of white and black soft tissue measuring up to 1.2 cm. RS-1

D. The specimen is received in formalin but was apparently

originally received fresh. It consists of a 195 g lung lobe. The specimen is labeled "right lower lobe". The specimen has a pink

and

purple serosal surface and measures 15 x 7 x 5.4 cm. The specimen has been incised prior to my examination and a portion of the specimen has been taken for research purposes. The incision is

into

a tumor measuring 3.5 x 3.2 x 3 cm.

E. Received in formalin labeled "level 7 lymph node" and consists of four pieces of white and black soft tissue varying from 0.4 to 2.4 cm. in greatest dimension. RS-2

MICROSCOPIC DESCRIPTION

- A. Lymph node pieces are negative for malignancy.
- B. There is no evidence of malignancy in any of 4 lymph nodes.
- C. There is no evidence of malignancy in any of 5 lymph nodes.
- D.

[page 2 of 2]
Tumor type: Adenocarcinoma
Tumor grade: 2 out of 3
Mitotic Index: 26 mitoses/10 HPFs (1 HPF = 0.19 sq mm)
Tumor size: 3.5 cm
Pulmonary margin of resection: Negative for malignancy
Pleura: Negative for malignancy
Vascular invasion: Absent
pTNM Stage: T2a N0
Non-tumorous lung: Benign reactive changes

E. There is no evidence of malignancy in any of 4 lymph nodes.

3, 4x4, 14

DIAGNOSIS

- A. Lymph node, R4, biopsy: Negative for malignancy
- B. Lymph nodes, right biopsy:
- There is no evidence of malignancy in any of 4 lymph nodes
- C. Lymph node, level 10, biopsy:
- There is no evidence of malignancy in any of 5 lymph nodes
- D. Lung, right lower lobe, resection:
- Moderately differentiated adenocarcinoma
- E. Lymph node, level 7, biopsy:
- There is no evidence of malignancy in any of 4 lymph nodes.

--- End Of Report ---

Source: NCI Genomic Data Commons file 7ccbeef5-74bc-47d1-be7d-b452c6f08580 (TCGA-44-5644.041E212A-2FDD-42AF-9326-9FB5FEF07126.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).